MMRF case MMRF_1713 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7cdd1fd1-ffd9-48af-8d58-5fda172919b1

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 60.1 years (21,943 days); ISS stage: III; Days to last known disease status: 1,169 days (3.2 years); Days to last follow up: 1,169 days (3.2 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 83 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 126 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 21 days; Days to treatment end: 28 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 84 days; Days to treatment end: 126 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 170 days; Days to treatment end: 170 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 171 days; Days to treatment end: 171 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 281 days; Days to treatment end: 350 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 350 days; Days to treatment end: 448 days (1.2 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,053 days (2.9 years); Days to treatment end: 1,148 days (3.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,148 days (3.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3: M Protein 4.89 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 36.2 mg/dL; Immunoglobulin G 66.5 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 6.05 µg/mL; Lactate Dehydrogenase 4.1 µkat/L; Hemoglobin 4.77 mmol/L; Leukocytes 9.3 ×10⁹/L; Absolute Neutrophil 4.71 ×10⁹/L; Platelets 256 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 15 mmol/L; Calcium 2.45 mmol/L; Albumin 37 g/L; Total Protein 11.4 g/dL; Glucose 5.01 mmol/L; C-Reactive Protein 0.082 mg/dL.
- Day 84 (ECOG 1): M Protein 0.4 g/dL; Hemoglobin 5.7 mmol/L; Leukocytes 9.6 ×10⁹/L; Platelets 268 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 7 g/dL; Glucose 6.55 mmol/L.
- Day 126 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.527 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.846 mg/dL; Hemoglobin 7.07 mmol/L; Leukocytes 7.5 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 5.23 mmol/L.
- Day 281 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.922 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.52 mg/dL; Immunoglobulin G 5.4 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.49 g/L; Hemoglobin 6.45 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 5.34 mmol/L.
- Day 316 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.883 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.95 mg/dL; Immunoglobulin G 6.35 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.41 g/L; Hemoglobin 6.45 mmol/L; Leukocytes 4.2 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 5.56 mmol/L.
- Day 448 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.63 mg/dL; Immunoglobulin G 7.18 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 6.32 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 5.06 mmol/L.
- Day 546 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.842 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.68 mg/dL; Immunoglobulin G 7.53 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.49 g/L; Hemoglobin 6.45 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 5.61 mmol/L.
- Day 630 (ECOG 2): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.837 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.61 mg/dL; Immunoglobulin G 8.12 g/L; Immunoglobulin A 0.74 g/L; Immunoglobulin M 0.57 g/L; Hemoglobin 6.39 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 5.72 mmol/L.
- Day 658 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.879 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.97 mg/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 0.98 g/L; Immunoglobulin M 0.72 g/L; Hemoglobin 6.01 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 64 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 6.4 g/dL; Glucose 5.39 mmol/L.
- Day 770 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.82 mg/dL; Immunoglobulin G 12.2 g/L; Immunoglobulin A 1.22 g/L; Immunoglobulin M 1.09 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 7 g/dL; Glucose 5.61 mmol/L.
- Day 840 (ECOG 2): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.43 mg/dL; Immunoglobulin G 9.37 g/L; Immunoglobulin A 1.05 g/L; Immunoglobulin M 0.83 g/L; Hemoglobin 6.82 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 5.83 mmol/L.
- Day 1,109 (ECOG 2): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.5 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 1.37 g/L; Immunoglobulin M 0.74 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 6.22 mmol/L.
- Day 1,169 (ECOG 2): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.42 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 1.29 g/L; Immunoglobulin M 0.58 g/L; Hemoglobin 6.7 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 6.9 g/dL; Glucose 10.5 mmol/L.

Other clinical attributes
- Day -3: Weight: 43 kg; Height: 161 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1713_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_1713_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
